Somatic mutation profile of tumor specimen MMRF_1180_1_BM_CD138pos (aliquot MMRF_1180_1_BM_CD138pos_T1_KAS5U_L01215) from MMRF case MMRF_1180, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.1 years (23,040 days).
Specimen MMRF_1180_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4fc3172-8e55-43c6-8985-26799e166e6a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1180_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1180_1_PB_Whole_C2_KAS5U_L01226; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/543db1f2-ec0f-489a-8cf0-ddc1dac4425c

The open-access MAF lists 485 somatic variants for this specimen: 176 protein-altering or splice-affecting, 63 silent, 246 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 148, 3'UTR 103, Silent 63, Intron 62, 5'UTR 39, 5'Flank 19, Nonsense Mutation 16, RNA 13, 3'Flank 10, Splice Region 5, Splice Site 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1900G>A p.D634N (on ENST00000288602 / NM_001374244.1; = p.D594N on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs397516896, COSV56061673, COSV56106240, COSV56184663; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- LDLR | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs137943601, CM045057, CM920451; ClinVar: likely benign / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SCN5A | c.3883G>A p.E1295K (on ENST00000333535 / NM_198056.3; = p.E1294K on NM_000335.5) | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as rs199473218, CM012464, COSV61127893; ClinVar: not provided / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ACTL6A | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66998633; called by muse, mutect2, varscan2
- ADAM11 | c.1511G>A p.R504Q | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775938319, COSV52344380; called by muse, mutect2, varscan2
- ATP2A2 | c.79G>C p.E27Q | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.142); catalogued as rs779803378; called by muse, mutect2, varscan2
- BAALC | c.389C>T p.S130L (on ENST00000297574 / NM_001364874.1; = p.S95L on NM_024812.3) | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as rs768711576, COSV52564034; called by muse, mutect2, varscan2
- C9orf116 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as COSV54093360; called by muse, mutect2, varscan2
- CBLB | c.2746G>C p.E916Q | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.475); catalogued as COSV51421377; called by muse, mutect2, varscan2
- CD58 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65665259; called by muse, mutect2
- CDH23 | c.2221G>A p.E741K | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.937); catalogued as COSV54932621; called by muse, mutect2, varscan2
- CDKN1B | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.073); catalogued as COSV57429884; called by muse, mutect2, varscan2
- CIDEC | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs988262334, COSV61062023; called by muse, mutect2, varscan2
- CLOCK | c.657C>G p.F219L | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as rs1455079663; called by muse, mutect2, varscan2
- CRB1 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 98/125 reads (78%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.989); catalogued as rs780719967; called by muse, mutect2, varscan2
- CTNNA3 | c.217G>T p.G73* | Nonsense Mutation (SNP) | VAF 52/111 reads (47%) | catalogued as COSV57718674, COSV57721676; called by muse, mutect2, varscan2
- DBF4 | c.1259C>G p.S420* | Nonsense Mutation (SNP) | VAF 37/73 reads (51%) | catalogued as COSV99719330; called by muse, mutect2, varscan2
- DCAF8 | c.1098G>C p.E366D | Missense Mutation (SNP) | VAF 67/97 reads (69%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as COSV58782748; called by muse, mutect2, varscan2
- DDX18 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.119); catalogued as rs1254497817; called by muse, mutect2, varscan2
- DHX9 | c.3283G>A p.E1095K | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.011); catalogued as rs1024133487; called by muse, mutect2, varscan2
- DOCK10 | c.6530C>T p.T2177M | Missense Mutation (SNP) | VAF 58/128 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs761955869, COSV51348269; called by muse, mutect2, varscan2
- DOK1 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.312); catalogued as COSV51208123; called by muse, mutect2, varscan2
- DSCAM | c.202G>T p.D68Y | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as rs367690354, COSV68648441; called by muse, mutect2, varscan2
- EEF1AKNMT | c.742G>A p.E248K (on ENST00000361735 / NM_015935.5; = p.E162K on NM_014955.3) | Missense Mutation (SNP) | VAF 139/180 reads (77%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as COSV62282557; called by muse, mutect2, varscan2
- ERLEC1 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as rs766535025; called by muse, mutect2
- FAT4 | c.4007C>A p.S1336Y | Missense Mutation (SNP) | VAF 63/144 reads (44%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.995); catalogued as rs1405481149, COSV67895724; called by muse, mutect2, varscan2
- FSIP2 | c.19453G>A p.V6485I | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs200703801, COSV100556851; called by muse, mutect2, varscan2
- GCM1 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 64/129 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.351); catalogued as rs748552826; called by muse, mutect2, varscan2
- GLI2 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT tolerated (0.54); PolyPhen benign (0.308); catalogued as rs759512271, COSV58054293; called by muse, mutect2, varscan2
- GMIP | c.1119G>C p.L373F | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.022); catalogued as COSV52559371; called by muse, varscan2
- H3C10 | c.191G>A p.R64K | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.37); catalogued as COSV60797419; called by muse, mutect2, varscan2
- HEATR3 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99590131; called by muse, mutect2, varscan2
- HIVEP3 | c.7103G>A p.R2368Q | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.884); catalogued as rs552982184, COSV99911123; called by muse, varscan2
- HNRNPU | c.68G>C p.R23P | Missense Mutation (SNP) | VAF 10/263 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51694839; called by muse, mutect2
- IGHV2-70 | c.91G>C p.V31L | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs373084365; called by muse, varscan2
- IGHV2-70 | c.75G>C p.E25D | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs181122105; called by muse, varscan2
- IGHV3-30 | c.53A>G p.Q18R | Missense Mutation (SNP) | VAF 20/219 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.631); catalogued as rs561462961; called by muse, varscan2
- IGLV3-1 | c.142G>T p.D48Y | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs368264723; called by muse, varscan2
- IGLV3-1 | c.335G>C p.S112T | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.216); catalogued as rs374018767; called by muse, mutect2, varscan2
- INSIG2 | c.670C>A p.Q224K | Missense Mutation (SNP) | VAF 74/145 reads (51%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.001); catalogued as COSV55522350; called by muse, mutect2, varscan2
- INTS6L | c.2147C>T p.S716F | Missense Mutation (SNP) | VAF 27/28 reads (96%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV100878012; called by muse, mutect2, varscan2
- ITGB1 | c.1656C>G p.F552L | Missense Mutation (SNP) | VAF 71/128 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.08); catalogued as COSV56488940; called by muse, mutect2, varscan2
- KCNJ16 | c.578G>C p.R193T | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52254137, COSV52256853; called by muse, mutect2, varscan2
- L3HYPDH | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT tolerated (0.79); PolyPhen benign (0.007); catalogued as COSV54201481; called by muse, mutect2, varscan2
- LONRF3 | c.497C>T p.S166L | Missense Mutation (SNP) | VAF 42/43 reads (98%) | SIFT tolerated (0.64); PolyPhen benign (0.014); catalogued as COSV59151153; called by muse, mutect2, varscan2
- MAGEB6B | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 28/29 reads (97%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as rs772391112; called by muse, mutect2, varscan2
- MAGEE1 | c.2216C>T p.S739L | Missense Mutation (SNP) | VAF 49/52 reads (94%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV63910121; called by muse, mutect2, varscan2
- MAGI3 | c.2284G>A p.E762K | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100287829, COSV56828513; called by muse, mutect2, varscan2
- MATN1 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs749462191; called by muse, mutect2, varscan2
- MYH10 | c.5608G>C p.E1870Q | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.67); catalogued as COSV52599940; called by muse, mutect2
- MYH14 | c.5719G>A p.E1907K | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs765998575; called by muse, mutect2, varscan2
- NAT10 | c.1894C>G p.H632D | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as COSV99139963; called by muse, mutect2, varscan2
- NEXN | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs748921688, COSV53942666; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP11 | c.2403C>G p.F801L | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100789797; called by muse, mutect2, varscan2
- PAK3 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 32/33 reads (97%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.608); catalogued as COSV53270129; called by muse, mutect2, varscan2
- PDHA2 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 69/139 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54781909; called by muse, mutect2, varscan2
- PHC1 | c.2635G>A p.E879K | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.837); catalogued as COSV104373908, COSV50003855; called by muse, mutect2, varscan2
- PPP1R9B | c.1075G>A p.V359I | Missense Mutation (SNP) | VAF 59/114 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs775326087; called by muse, mutect2, varscan2
- PTGFRN | c.2146G>A p.E716K | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT tolerated (0.28); PolyPhen benign (0.058); catalogued as rs779207353; called by muse, mutect2, varscan2
- PTPRT | c.2176+1G>C p.X726_splice | Splice Site (SNP) | VAF 56/109 reads (51%) | catalogued as COSV61977510; called by muse, mutect2, varscan2
- PUS10 | c.232G>C p.D78H | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as COSV57454858; called by muse, mutect2, varscan2
- RBM28 | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 43/76 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV56161542, COSV99775575; called by muse, mutect2, varscan2
- REM1 | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 73/151 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs370405435, COSV99146666; called by muse, mutect2, varscan2
- RNF217 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 77/144 reads (53%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.023); catalogued as rs777176681; called by muse, mutect2, varscan2
- RRP36 | c.633C>A p.F211L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs1330724262; called by muse, mutect2, varscan2
- RUFY1 | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.161); catalogued as rs1172891335, COSV60162051; called by muse, mutect2, varscan2
- RXFP1 | c.2166G>A p.M722I | Missense Mutation (SNP) | VAF 57/111 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as rs1181171544; called by muse, mutect2, varscan2
- RYR2 | c.12873C>A p.F4291L | Missense Mutation (SNP) | VAF 166/230 reads (72%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV63678838, COSV63708026; called by muse, mutect2, varscan2
- SGSM1 | c.1706C>G p.S569* | Nonsense Mutation (SNP) | VAF 33/59 reads (56%) | catalogued as COSV68513862; called by muse, mutect2, varscan2
- SLC22A1 | c.1537C>T p.L513F | Missense Mutation (SNP) | VAF 60/147 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs751407403; called by muse, mutect2, varscan2
- SLC6A4 | c.1791G>T p.L597F | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT tolerated (0.73); PolyPhen benign (0.405); catalogued as rs762463325; called by muse, mutect2, varscan2
- SOSTDC1 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.019); catalogued as COSV61049288; called by muse, mutect2, varscan2
- TMPO | c.1012C>T p.Q338* | Nonsense Mutation (SNP) | VAF 42/100 reads (42%) | catalogued as rs1028785602; called by muse, mutect2, varscan2
- TRIO | c.5275G>A p.G1759R | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.91); catalogued as rs769756833; called by muse, mutect2, varscan2
- VAT1 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs760932116, COSV63039709; called by muse, mutect2, varscan2
- VRK2 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as rs1228024879, COSV60876261; called by muse, mutect2, varscan2
- WNT2 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.952); catalogued as COSV99626515; called by muse, mutect2, varscan2
- XRN2 | c.190C>T p.H64Y | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65871993; called by muse, mutect2, varscan2
- ZBTB40 | c.472C>T p.H158Y | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as COSV65144795; called by muse, mutect2, varscan2
- ZEB1 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs369476602; called by muse, mutect2, varscan2
- ABCD2 | c.358C>G p.L120V | Missense Mutation (SNP) | VAF 72/155 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ABCF3 | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 109/200 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANK2 | c.6187G>A p.E2063K | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- ANXA4 | c.159G>C p.E53D | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- AP000829.1 | n.889+6T>G | Splice Region (SNP) | VAF 18/37 reads (49%) | called by muse, mutect2, varscan2
- ARSI | c.879C>G p.I293M | Missense Mutation (SNP) | VAF 95/189 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- BNC1 | c.364G>C p.D122H | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- BOLL | c.716C>G p.T239S | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- BPNT2 | c.945G>T p.M315I | Missense Mutation (SNP) | VAF 72/131 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- C12orf4 | c.1339G>A p.D447N | Missense Mutation (SNP) | VAF 70/123 reads (57%) | SIFT tolerated (0.52); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- C3orf80 | c.213C>A p.F71L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- C8orf58 | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- CABP5 | c.227T>G p.I76S | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- CCDC112 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CETN3 | c.270G>A p.V90= | Splice Region (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
- CLDN20 | c.242G>A p.R81K | Missense Mutation (SNP) | VAF 63/127 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- CLNS1A | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CPM | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 58/112 reads (52%) | SIFT tolerated (0.39); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- CRYBA2 | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CUL5 | c.815C>T p.S272L | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- DCUN1D2 | c.666G>C p.M222I | Missense Mutation (SNP) | VAF 41/41 reads (100%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- DIS3 | c.1558G>T p.D520Y | Missense Mutation (SNP) | VAF 18/18 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DPYS | c.950+4A>C | Splice Region (SNP) | VAF 23/52 reads (44%) | called by muse, mutect2, varscan2
- DYNC2H1 | c.1255C>G p.Q419E | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- ECH1 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 60/100 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.076); called by muse, varscan2
- FAF1 | c.536C>T p.S179L | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM13B | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 92/183 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FAM205A | c.1687G>A p.E563K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.061); called by mutect2, varscan2
- FAT4 | c.4795C>T p.L1599F | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FBLN7 | c.203C>G p.S68C | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- FOXA3 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 54/90 reads (60%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- FOXO3 | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 5/15 reads (33%) | called by muse, mutect2, varscan2
- GADD45A | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- GBF1 | c.1173G>C p.Q391H (on ENST00000369983 / NM_001377137.1; = p.Q390H on NM_004193.3) | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- H2AP | c.86G>T p.R29M | Missense Mutation (SNP) | VAF 82/85 reads (96%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- HECW2 | c.3667G>C p.D1223H | Missense Mutation (SNP) | VAF 60/113 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HLA-DPA1 | c.573C>A p.F191L | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IGHA1 | c.865dup p.T289Nfs*47 | Frame Shift Ins (INS) | VAF 11/39 reads (28%) | called by mutect2, pindel, varscan2
- IGKV2-28 | c.62A>C p.D21A | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.246); called by muse, varscan2
- IL17RD | c.1816G>C p.E606Q | Missense Mutation (SNP) | VAF 58/118 reads (49%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- IPO9 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- ITGAV | c.1988A>C p.N663T | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- JMJD1C | c.4318C>T p.Q1440* | Nonsense Mutation (SNP) | VAF 62/132 reads (47%) | called by muse, mutect2, varscan2
- KAT2A | c.2374C>G p.L792V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- KIF23 | c.2042G>T p.R681I | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- KLF7 | c.350C>G p.S117C | Missense Mutation (SNP) | VAF 49/87 reads (56%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- KLK11 | c.631C>G p.P211A (on ENST00000594768 / NM_144947.3; = p.P179A on NM_006853.3) | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- L3MBTL3 | c.291C>G p.V97= | Splice Region (SNP) | VAF 11/26 reads (42%) | called by muse, mutect2
- LIFR | c.2863G>C p.E955Q | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- MOCOS | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MON1A | c.254_268del p.A85_L90delinsV | In Frame Del (DEL) | VAF 25/61 reads (41%) | called by mutect2, pindel, varscan2
- MYH10 | c.1768G>C p.E590Q | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.875); called by muse, mutect2
- MYOM2 | c.3247G>A p.E1083K | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- NR4A2 | c.80C>A p.S27* | Nonsense Mutation (SNP) | VAF 85/154 reads (55%) | called by muse, mutect2, varscan2
- PARP6 | c.79C>T p.Q27* | Nonsense Mutation (SNP) | VAF 15/56 reads (27%) | called by muse, mutect2, varscan2
- PATZ1 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 65/131 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- PCDHGB5 | c.645G>C p.L215F | Missense Mutation (SNP) | VAF 77/156 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- PCLO | c.12809C>A p.T4270N | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PCNX3 | c.1649C>T p.A550V | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT tolerated (0.16); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PHC3 | c.300+1del p.X100_splice (on ENST00000494943 / NM_001308116.2; = p.X112_splice on NM_024947.4) | Splice Site (DEL) | VAF 4/17 reads (24%) | called by mutect2, pindel, varscan2
- PHTF1 | c.108G>C p.L36F | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLA2R1 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (0.41); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PLB1 | c.1323G>A p.A441= | Splice Region (SNP) | VAF 97/187 reads (52%) | called by muse, mutect2, varscan2
- PNN | c.1856G>A p.R619K | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- POU5F2 | c.88G>C p.D30H | Missense Mutation (SNP) | VAF 39/63 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- PRDM5 | c.703C>T p.Q235* | Nonsense Mutation (SNP) | VAF 55/135 reads (41%) | called by muse, mutect2, varscan2
- PRMT9 | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- PROM2 | c.658G>C p.E220Q | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.55); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PURA | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- RASA1 | c.1854C>G p.I618M | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- RMI1 | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- SCAF1 | c.3003_3004insGGTA p.P1002Gfs*3 | Frame Shift Ins (INS) | VAF 25/43 reads (58%) | called by mutect2, varscan2
- SLC28A3 | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2, varscan2
- SMC1A | c.543C>G p.D181E | Missense Mutation (SNP) | VAF 66/68 reads (97%) | SIFT tolerated (0.55); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- SOWAHC | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPAG4 | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT tolerated (0.05); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SSTR5 | c.92G>T p.G31V | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- SSUH2 | c.623C>G p.S208* | Nonsense Mutation (SNP) | VAF 44/84 reads (52%) | called by muse, mutect2, varscan2
- SYNE2 | c.20007G>C p.L6669F | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- TEDDM1 | c.571G>T p.D191Y | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TEX35 | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 47/222 reads (21%) | called by muse, mutect2, varscan2
- THBS1 | c.2468A>G p.D823G | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- THUMPD3 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- TLR8 | c.824C>T p.S275L (on ENST00000218032 / NM_138636.5; = p.S293L on NM_016610.4) | Missense Mutation (SNP) | VAF 65/66 reads (98%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRAF2 | c.199C>T p.Q67* | Nonsense Mutation (SNP) | VAF 41/90 reads (46%) | called by muse, mutect2, varscan2
- TRAF2 | c.399del p.T134Pfs*28 | Frame Shift Del (DEL) | VAF 44/114 reads (39%) | called by mutect2, pindel, varscan2
- TRIM42 | c.1733G>T p.G578V | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TRPM6 | c.2181G>A p.M727I | Missense Mutation (SNP) | VAF 45/71 reads (63%) | SIFT tolerated (0.09); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- TSPAN9 | c.261C>G p.F87L | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- USP7 | c.510del p.F170Lfs*7 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | called by mutect2*, pindel
- VCP | c.2287C>T p.Q763* | Nonsense Mutation (SNP) | VAF 51/85 reads (60%) | called by muse, mutect2, varscan2
- VWDE | c.4563C>G p.I1521M | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ZBTB12 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZNF3 | c.1069C>T p.Q357* | Nonsense Mutation (SNP) | VAF 38/77 reads (49%) | called by muse, mutect2, varscan2
- ZNF549 | c.973A>G p.T325A (on ENST00000376233 / NM_001199295.2; = p.T312A on NM_153263.2) | Missense Mutation (SNP) | VAF 67/124 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ZNF644 | c.2623G>T p.E875* | Nonsense Mutation (SNP) | VAF 29/54 reads (54%) | called by muse, mutect2, varscan2
- ABCA13 | c.13881C>G p.L4627= | Silent (SNP) | VAF 50/100 reads (50%) | catalogued as rs779214725; called by muse, mutect2, varscan2
- ACAA1 | c.234G>A p.L78= | Silent (SNP) | VAF 64/132 reads (48%) | called by muse, mutect2, varscan2
- AHNAK2 | c.726C>T p.L242= | Silent (SNP) | VAF 32/63 reads (51%) | called by muse, mutect2
- AKAP13 | c.7368C>T p.V2456= (on ENST00000394518 / NM_007200.5; = p.V2460= on NM_006738.6) | Silent (SNP) | VAF 24/47 reads (51%) | catalogued as rs369617568; called by muse, mutect2, varscan2
- ALPP | c.759G>A p.K253= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as COSV67396123; called by muse, mutect2, varscan2
- ATP12A | c.324C>G p.L108= | Silent (SNP) | VAF 31/33 reads (94%) | catalogued as COSV54513065; called by muse, mutect2, varscan2
- CCR7 | c.519C>T p.L173= | Silent (SNP) | VAF 59/103 reads (57%) | catalogued as rs1189789925; called by muse, mutect2, varscan2
- CD163L1 | c.2265G>A p.S755= | Silent (SNP) | VAF 59/124 reads (48%) | catalogued as rs927645840, COSV58016797; called by muse, mutect2, varscan2
- CD2AP | c.189C>T p.F63= | Silent (SNP) | VAF 58/138 reads (42%) | called by muse, mutect2, varscan2
- CREBBP | c.3282C>G p.L1094= | Silent (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- CRYBA1 | c.144C>T p.F48= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as rs866741668; called by muse, mutect2, varscan2
- DOCK1 | c.5421C>T p.S1807= | Silent (SNP) | VAF 63/113 reads (56%) | catalogued as rs755126443, COSV54741416; called by muse, mutect2, varscan2
- FAM50B | c.705C>T p.L235= | Silent (SNP) | VAF 89/148 reads (60%) | called by muse, mutect2, varscan2
- FAM83C | c.1488G>A p.E496= | Silent (SNP) | VAF 67/140 reads (48%) | called by muse, mutect2, varscan2
- FSIP2 | c.5307C>T p.L1769= | Silent (SNP) | VAF 16/35 reads (46%) | called by muse, mutect2, varscan2
- GOLPH3L | c.294G>A p.K98= | Silent (SNP) | VAF 27/104 reads (26%) | called by muse, mutect2, varscan2
- GPR156 | c.735G>C p.L245= | Silent (SNP) | VAF 13/26 reads (50%) | called by muse, mutect2, varscan2
- GPR75 | c.1050G>A p.G350= | Silent (SNP) | VAF 61/131 reads (47%) | called by muse, mutect2, varscan2
- HNRNPA2B1 | c.111G>A p.L37= (on ENST00000354667 / NM_031243.3; = p.L25= on NM_002137.4) | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as COSV100522850; called by muse, mutect2, varscan2
- IGDCC3 | c.2268G>A p.G756= | Silent (SNP) | VAF 36/68 reads (53%) | called by muse, mutect2, varscan2
- IGF2BP3 | c.66C>T p.F22= | Silent (SNP) | VAF 32/60 reads (53%) | catalogued as COSV51681440; called by muse, mutect2, varscan2
- IGKJ5 | c.40C>T p.*14= | Silent (SNP) | VAF 58/126 reads (46%) | catalogued as rs181580600; called by muse, mutect2, varscan2
- IGLL5 | c.138A>G p.Q46= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs554492007, COSV73250786; called by muse, varscan2
- IL1R2 | c.558G>A p.V186= | Silent (SNP) | VAF 23/53 reads (43%) | called by muse, mutect2, varscan2
- IL6R | c.606C>T p.F202= | Silent (SNP) | VAF 109/152 reads (72%) | called by muse, mutect2, varscan2
- INPPL1 | c.159G>A p.A53= | Silent (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- INPPL1 | c.3693C>T p.I1231= | Silent (SNP) | VAF 37/73 reads (51%) | called by muse, mutect2, varscan2
- KCNU1 | c.2781G>T p.V927= | Silent (SNP) | VAF 39/87 reads (45%) | called by muse, mutect2, varscan2
- KIRREL3 | c.1092G>A p.L364= | Silent (SNP) | VAF 29/61 reads (48%) | called by muse, mutect2, varscan2
- KMT2B | c.2499C>G p.V833= | Silent (SNP) | VAF 47/97 reads (48%) | called by muse, mutect2, varscan2
- LRATD2 | c.450G>A p.V150= | Silent (SNP) | VAF 28/67 reads (42%) | called by muse, mutect2, varscan2
- LRRK1 | c.4540C>T p.L1514= | Silent (SNP) | VAF 59/106 reads (56%) | called by muse, mutect2, varscan2
- MAVS | c.1323C>T p.I441= | Silent (SNP) | VAF 37/78 reads (47%) | catalogued as COSV63927389; called by muse, mutect2, varscan2
- MICAL3 | c.4002C>T p.I1334= | Silent (SNP) | VAF 62/138 reads (45%) | catalogued as COSV71588031; called by muse, mutect2, varscan2
- MINDY2 | c.321G>A p.K107= | Silent (SNP) | VAF 30/73 reads (41%) | catalogued as rs1301568730; called by muse, mutect2, varscan2
- MKI67 | c.2676G>A p.K892= | Silent (SNP) | VAF 11/136 reads (8%) | called by muse, mutect2
- MMP3 | c.456G>C p.L152= | Silent (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2, varscan2
- MYC | c.42C>T p.L14= (on ENST00000377970; = p.L29= on NM_002467.6) | Silent (SNP) | VAF 92/190 reads (48%) | catalogued as rs758197763, COSV52381996; called by muse, varscan2
- NFATC1 | c.360C>T p.I120= | Silent (SNP) | VAF 75/156 reads (48%) | catalogued as rs780043422; ClinVar: likely benign; called by muse, mutect2, varscan2
- OBSCN | c.16650G>A p.K5550= | Silent (SNP) | VAF 126/169 reads (75%) | called by muse, mutect2, varscan2
- OR4P4 | c.375C>T p.C125= | Silent (SNP) | VAF 41/41 reads (100%) | catalogued as COSV100111858; called by muse, mutect2, varscan2
- PLXND1 | c.3561C>T p.I1187= | Silent (SNP) | VAF 32/113 reads (28%) | called by muse, mutect2, varscan2
- POLR2I | c.33C>T p.F11= | Silent (SNP) | VAF 24/50 reads (48%) | called by muse, mutect2, varscan2
- PRDM9 | c.1701C>T p.L567= | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as COSV57005729, COSV99689812; called by muse, mutect2, varscan2
- PRR11 | c.888G>T p.R296= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV51876659; called by muse, mutect2, varscan2
- PSEN1 | c.1029G>A p.Q343= | Silent (SNP) | VAF 45/78 reads (58%) | catalogued as COSV99998069; called by muse, mutect2, varscan2
- PTPRM | c.3399G>A p.R1133= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV100155611; called by muse, mutect2, varscan2
- RCOR2 | c.1098G>A p.V366= | Silent (SNP) | VAF 71/152 reads (47%) | called by muse, mutect2, varscan2
- RHAG | c.1131G>A p.L377= | Silent (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
- ROMO1 | c.48C>T p.F16= | Silent (SNP) | VAF 75/130 reads (58%) | called by muse, mutect2, varscan2
- SCN4A | c.2145C>T p.A715= | Silent (SNP) | VAF 88/160 reads (55%) | catalogued as COSV71125632; called by muse, mutect2, varscan2
- SLC37A2 | c.666C>T p.G222= | Silent (SNP) | VAF 31/50 reads (62%) | catalogued as rs531000167; called by muse, mutect2, varscan2
- SLIT1 | c.708C>T p.I236= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as rs900242418, COSV99820935; called by muse, mutect2, varscan2
- SUPT20HL1 | c.1020G>A p.A340= | Silent (SNP) | VAF 62/62 reads (100%) | catalogued as rs748377594; called by muse, mutect2, varscan2
- TAPBP | c.1267C>T p.L423= | Silent (SNP) | VAF 45/76 reads (59%) | called by muse, mutect2, varscan2
- THBS1 | c.3336C>T p.L1112= | Silent (SNP) | VAF 33/85 reads (39%) | called by muse, mutect2, varscan2
- TRANK1 | c.5793C>T p.L1931= | Silent (SNP) | VAF 46/93 reads (49%) | called by muse, mutect2, varscan2
- TTC28 | c.696G>A p.L232= | Silent (SNP) | VAF 20/42 reads (48%) | called by muse, mutect2, varscan2
- UACA | c.2556G>A p.K852= | Silent (SNP) | VAF 34/71 reads (48%) | called by muse, mutect2, varscan2
- UMPS | c.882G>A p.V294= | Silent (SNP) | VAF 42/78 reads (54%) | called by muse, mutect2, varscan2
- VWA5B2 | c.753C>T p.T251= | Silent (SNP) | VAF 43/96 reads (45%) | called by muse, mutect2, varscan2
- ZBTB38 | c.237C>G p.L79= | Silent (SNP) | VAF 48/111 reads (43%) | called by muse, mutect2, varscan2
- ZNF318 | c.318C>T p.F106= | Silent (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2
- ABHD17A | c.*212A>C | 3'UTR (SNP) | VAF 15/28 reads (54%) | called by muse, mutect2, varscan2
- AC211429.1 | n.211G>A | RNA (SNP) | VAF 9/15 reads (60%) | called by muse, mutect2, varscan2
- ACADVL | c.139-66C>T | Intron (SNP) | VAF 58/99 reads (59%) | catalogued as rs1029039003; called by muse, mutect2, varscan2
- ACYP2 | chr2:54115480 C>T | 5'Flank (SNP) | VAF 18/33 reads (55%) | called by muse, mutect2, varscan2
- ADARB2 | c.*325G>A | 3'UTR (SNP) | VAF 35/71 reads (49%) | catalogued as rs905574159; called by muse, mutect2, varscan2
- ADRB2 | c.-214G>A | 5'UTR (SNP) | VAF 66/122 reads (54%) | catalogued as rs1288556235; called by muse, mutect2, varscan2
- AIG1 | chr6:143339748 G>A | 3'Flank (SNP) | VAF 43/100 reads (43%) | called by muse, mutect2, varscan2
- AL133373.3 | n.973C>G | RNA (SNP) | VAF 12/23 reads (52%) | called by muse, varscan2
- AL662844.4 | n.398C>T | RNA (SNP) | VAF 20/39 reads (51%) | catalogued as rs1007522836; called by muse, mutect2, varscan2
- ANGEL1 | c.1381-288C>G | Intron (SNP) | VAF 13/36 reads (36%) | called by muse, mutect2, varscan2
- ANK3 | c.*9G>A | 3'UTR (SNP) | VAF 98/221 reads (44%) | catalogued as rs373606776; called by muse, mutect2, varscan2
- ANKRD30B | c.*60C>T | 3'UTR (SNP) | VAF 13/35 reads (37%) | called by muse, mutect2, varscan2
- ARL14 | c.*399C>T | 3'UTR (SNP) | VAF 31/61 reads (51%) | catalogued as rs973264444; called by muse, mutect2, varscan2
- ASTN1 | c.*2862G>T | 3'UTR (SNP) | VAF 28/132 reads (21%) | called by muse, mutect2, varscan2
- ATAD2 | c.*466G>C | 3'UTR (SNP) | VAF 25/50 reads (50%) | catalogued as rs1275042281; called by muse, mutect2
- ATP6V0E1 | c.*323G>A | 3'UTR (SNP) | VAF 41/86 reads (48%) | called by muse, mutect2, varscan2
- AVIL | c.1963-213G>C | Intron (SNP) | VAF 66/154 reads (43%) | called by muse, mutect2, varscan2
- B3GALT4 | c.-217G>A | 5'UTR (SNP) | VAF 13/21 reads (62%) | catalogued as rs1336232136; called by muse, mutect2, varscan2
- BACE2 | chr21:41167590 G>A | 5'Flank (SNP) | VAF 22/42 reads (52%) | called by muse, mutect2, varscan2
- BAZ2A | c.*665G>C | 3'UTR (SNP) | VAF 27/65 reads (42%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021275 C>T | 5'Flank (SNP) | VAF 50/105 reads (48%) | catalogued as rs765420246, COSV55847946, COSV55851575; called by muse, mutect2, varscan2
- BLOC1S2 | c.*301C>G | 3'UTR (SNP) | VAF 33/72 reads (46%) | called by muse, mutect2, varscan2
- BOK | c.*58C>G | 3'UTR (SNP) | VAF 23/48 reads (48%) | catalogued as COSV100572244; called by muse, mutect2, varscan2
- BROX | c.*71C>T | 3'UTR (SNP) | VAF 32/141 reads (23%) | called by muse, mutect2, varscan2
- C10orf88 | c.*706C>G | 3'UTR (SNP) | VAF 32/92 reads (35%) | catalogued as rs183575042; called by muse, mutect2, varscan2
- C12orf50 | c.1127-1318C>T | Intron (SNP) | VAF 31/63 reads (49%) | catalogued as rs1378229077; called by muse, mutect2, varscan2
- C12orf66 | c.*546C>G | 3'UTR (SNP) | VAF 22/60 reads (37%) | called by muse, mutect2, varscan2
- C1QTNF2 | c.*713T>A | 3'UTR (SNP) | VAF 22/50 reads (44%) | called by muse, mutect2, varscan2
- C1orf109 | c.*655G>A | 3'UTR (SNP) | VAF 18/43 reads (42%) | called by muse, mutect2, varscan2
- C20orf194 | c.2018+72C>T | Intron (SNP) | VAF 31/56 reads (55%) | called by muse, mutect2, varscan2
- C2orf73 | c.*478G>C | 3'UTR (SNP) | VAF 20/43 reads (47%) | called by muse, mutect2, varscan2
- C3AR1 | c.*528G>A | 3'UTR (SNP) | VAF 11/20 reads (55%) | called by muse, mutect2, varscan2
- C3orf52 | c.*824G>C | 3'UTR (SNP) | VAF 15/47 reads (32%) | called by muse, mutect2, varscan2
- C4orf50 | chr4:5989698 G>T | 5'Flank (SNP) | VAF 63/129 reads (49%) | catalogued as rs1242969618; called by muse, mutect2, varscan2
- CACNG8 | c.*586C>T | 3'UTR (SNP) | VAF 32/64 reads (50%) | called by muse, mutect2, varscan2
- CAMK4 | c.*10121G>A | 3'UTR (SNP) | VAF 9/14 reads (64%) | called by muse, mutect2, varscan2
- CAMLG | c.172+137C>T | Intron (SNP) | VAF 16/38 reads (42%) | called by muse, mutect2
- CAMTA2 | c.-65+565G>A | Intron (SNP) | VAF 22/53 reads (42%) | called by muse, mutect2, varscan2
- CARD8 | c.351-915C>G | Intron (SNP) | VAF 5/78 reads (6%) | called by muse, mutect2
- CC2D2A | c.247+1217G>A | Intron (SNP) | VAF 42/83 reads (51%) | called by muse, mutect2, varscan2
- CCDC65 | c.-138G>A | 5'UTR (SNP) | VAF 35/71 reads (49%) | called by muse, mutect2, varscan2
- CCNO | c.*62G>A | 3'UTR (SNP) | VAF 48/100 reads (48%) | called by muse, mutect2, varscan2
- CCNT1 | c.*3981C>T | 3'UTR (SNP) | VAF 19/46 reads (41%) | called by muse, mutect2, varscan2
- CDK9 | c.*757C>G | 3'UTR (SNP) | VAF 14/45 reads (31%) | called by muse, mutect2, varscan2
- CDK9 | c.*1096C>T | 3'UTR (SNP) | VAF 20/44 reads (45%) | called by muse, varscan2
- CDK9 | c.*1140A>G | 3'UTR (SNP) | VAF 14/37 reads (38%) | called by muse, varscan2
- CDKN2B | c.*1559C>T | 3'UTR (SNP) | VAF 25/50 reads (50%) | called by muse, mutect2, varscan2
- CHST5 | c.*224C>T | 3'UTR (SNP) | VAF 51/99 reads (52%) | called by muse, mutect2, varscan2
- CIB4 | c.187-10212G>C | Intron (SNP) | VAF 29/74 reads (39%) | catalogued as COSV56599084; called by muse, mutect2, varscan2
- CKAP5 | c.4027+173G>A | Intron (SNP) | VAF 17/47 reads (36%) | catalogued as rs755225919, COSV100370218; called by muse, mutect2, varscan2
- CLASP2 | c.*2066A>G | 3'UTR (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2, varscan2
- CNN3 | c.-204C>T | 5'UTR (SNP) | VAF 18/28 reads (64%) | catalogued as rs1015725917; called by muse, mutect2, varscan2
- COCH | c.1156-12C>G | Intron (SNP) | VAF 22/37 reads (59%) | called by muse, mutect2, varscan2
- COG2 | c.-119C>T | 5'UTR (SNP) | VAF 33/72 reads (46%) | called by muse, mutect2
- CREBBP | c.-748C>T | 5'UTR (SNP) | VAF 14/29 reads (48%) | called by muse, mutect2, varscan2
- CUL4A | chr13:113208257 C>T | 5'Flank (SNP) | VAF 90/93 reads (97%) | called by muse, mutect2, varscan2
- CYFIP1 | c.1675-66G>C | Intron (SNP) | VAF 49/110 reads (45%) | called by muse, mutect2, varscan2
- DAD1 | c.-6G>C | 5'UTR (SNP) | VAF 43/74 reads (58%) | called by muse, mutect2, varscan2
- DAZAP2 | c.*559C>G | 3'UTR (SNP) | VAF 56/112 reads (50%) | called by muse, mutect2, varscan2
- DBF4B | c.*970G>A | 3'UTR (SNP) | VAF 27/55 reads (49%) | called by muse, mutect2, varscan2
- DCHS2 | n.3837G>A | RNA (SNP) | VAF 40/81 reads (49%) | catalogued as COSV61771681; called by muse, mutect2, varscan2
- DCLK3 | c.*1858C>G | 3'UTR (SNP) | VAF 54/114 reads (47%) | called by muse, mutect2, varscan2
- DDX19B | c.296+20C>T | Intron (SNP) | VAF 47/120 reads (39%) | catalogued as rs1299208115, COSV99850070; called by muse, mutect2, varscan2
- DENND6B | c.217-20C>T | Intron (SNP) | VAF 44/119 reads (37%) | catalogued as rs375670858; called by muse, mutect2, varscan2
- DLC1 | c.*1420G>C | 3'UTR (SNP) | VAF 37/76 reads (49%) | called by muse, mutect2, varscan2
- DLX3 | c.*1481A>C | 3'UTR (SNP) | VAF 23/40 reads (58%) | called by muse, mutect2, varscan2
- DLX3 | c.*305C>G | 3'UTR (SNP) | VAF 38/81 reads (47%) | called by muse, mutect2, varscan2
- DNAJC18 | c.*2763G>A | 3'UTR (SNP) | VAF 22/41 reads (54%) | called by muse, mutect2, varscan2
- DOCK5 | c.*393G>C | 3'UTR (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- DPP10 | c.*1918G>A | 3'UTR (SNP) | VAF 51/95 reads (54%) | catalogued as rs1284472824; called by muse, mutect2, varscan2
- DTWD1 | c.*405C>T | 3'UTR (SNP) | VAF 26/65 reads (40%) | called by muse, mutect2, varscan2
- DUSP11 | c.*348G>A | 3'UTR (SNP) | VAF 43/77 reads (56%) | called by muse, mutect2, varscan2
- EEA1 | c.*2248C>T | 3'UTR (SNP) | VAF 32/62 reads (52%) | catalogued as rs1404772229; called by muse, mutect2, varscan2
- EFR3A | c.*2020T>C | 3'UTR (SNP) | VAF 31/71 reads (44%) | called by muse, mutect2, varscan2
- EMBP1 | n.945C>G | RNA (SNP) | VAF 64/113 reads (57%) | called by muse, mutect2, varscan2
- EML2 | chr19:45642157 G>A | 5'Flank (SNP) | VAF 37/72 reads (51%) | called by muse, mutect2, varscan2
- ENAM | c.*353G>A | 3'UTR (SNP) | VAF 34/71 reads (48%) | called by muse, mutect2
- ENPP1 | c.*4618_*4621del | 3'UTR (DEL) | VAF 39/97 reads (40%) | called by mutect2, pindel, varscan2
- ENY2 | c.*1177C>T | 3'UTR (SNP) | VAF 20/42 reads (48%) | called by muse, mutect2, varscan2
- ESPNP | n.1843G>A | RNA (SNP) | VAF 5/27 reads (19%) | catalogued as rs769323762; called by muse, mutect2, varscan2
- FAM205BP | n.1689G>A | RNA (SNP) | VAF 23/104 reads (22%) | called by muse, mutect2, varscan2
- FAS | c.-311G>A | 5'UTR (SNP) | VAF 16/28 reads (57%) | called by muse, varscan2
- FAXDC2 | c.845+64C>T | Intron (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- FBN2 | c.-11C>T | 5'UTR (SNP) | VAF 49/101 reads (49%) | catalogued as rs1313923629, COSV99325834, COSV99331119; called by muse, mutect2, varscan2
- FXYD2 | c.-47G>A | 5'UTR (SNP) | VAF 72/151 reads (48%) | called by muse, mutect2, varscan2
- GALNT16 | c.-69G>C | 5'UTR (SNP) | VAF 20/47 reads (43%) | called by muse, mutect2, varscan2
- GFRA2 | c.41-85C>T | Intron (SNP) | VAF 97/186 reads (52%) | called by muse, mutect2, varscan2
- GINM1 | c.718-374G>A | Intron (SNP) | VAF 32/60 reads (53%) | called by muse, mutect2, varscan2
- GOSR2 | c.40+78C>G | Intron (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2, varscan2
- GPRC5A | c.*3986G>C | 3'UTR (SNP) | VAF 27/53 reads (51%) | called by muse, mutect2, varscan2
- GRIK4 | c.907-5560G>A | Intron (SNP) | VAF 5/11 reads (45%) | called by muse, mutect2, varscan2
- GRIK4 | c.907-4909G>A | Intron (SNP) | VAF 18/35 reads (51%) | called by muse, mutect2, varscan2
- H2AC17 | c.*5T>C | 3'UTR (SNP) | VAF 57/127 reads (45%) | called by muse, mutect2, varscan2
- HAVCR1 | c.*21G>A | 3'UTR (SNP) | VAF 73/159 reads (46%) | catalogued as rs1415210771; called by muse, mutect2, varscan2
- HDAC9 | c.25+17C>T | Intron (SNP) | VAF 47/99 reads (47%) | catalogued as rs1006429037; called by muse, mutect2, varscan2
- HMBOX1 | c.*1834G>T | 3'UTR (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
- HNRNPL | c.881-1093C>G | Intron (SNP) | VAF 53/108 reads (49%) | called by muse, mutect2, varscan2
- HSPA1B | c.-172C>T | 5'UTR (SNP) | VAF 57/107 reads (53%) | catalogued as rs1178648643; called by muse, mutect2, varscan2
- ICE1 | c.178+26T>C | Intron (SNP) | VAF 29/61 reads (48%) | called by muse, mutect2, varscan2
- IFNA16 | c.*245G>T | 3'UTR (SNP) | VAF 44/87 reads (51%) | called by muse, mutect2, varscan2
- IKZF1 | c.41-75C>T | Intron (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2, varscan2
- IL16 | chr15:81311768 G>A | 3'Flank (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2
- IMP4 | chr2:130342879 C>T | 5'Flank (SNP) | VAF 63/121 reads (52%) | catalogued as rs375593565; called by muse, mutect2, varscan2
- IPO7 | c.-88G>A | 5'UTR (SNP) | VAF 39/82 reads (48%) | called by muse, mutect2, varscan2
- ITPKB | chr1:226737474 G>A | 5'Flank (SNP) | VAF 11/62 reads (18%) | catalogued as COSV99684659; called by muse, mutect2, varscan2
- ITPR3 | c.-237G>A | 5'UTR (SNP) | VAF 8/9 reads (89%) | called by muse, mutect2, varscan2
- KIAA0100 | c.248+116G>A | Intron (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2, varscan2
- KIAA1958 | c.1172-26887G>C | Intron (SNP) | VAF 60/111 reads (54%) | called by muse, mutect2, varscan2
- KLHL4 | c.*494T>G | 3'UTR (SNP) | VAF 22/24 reads (92%) | called by muse, mutect2, varscan2
- KRTAP1-1 | c.*37C>T | 3'UTR (SNP) | VAF 16/45 reads (36%) | called by muse, mutect2, varscan2
- LAG3 | c.1301-56G>A | Intron (SNP) | VAF 59/131 reads (45%) | called by muse, mutect2, varscan2
- LAX1 | c.-273G>A | 5'UTR (SNP) | VAF 36/139 reads (26%) | called by muse, mutect2, varscan2
- LBX2 | chr2:74503293 C>T | 5'Flank (SNP) | VAF 63/120 reads (53%) | called by muse, mutect2, varscan2
- LCP2 | c.1323+622_1323+627del | Intron (DEL) | VAF 11/41 reads (27%) | called by mutect2, varscan2
- LIG3 | c.*4645G>C | 3'UTR (SNP) | VAF 40/86 reads (47%) | called by muse, mutect2, varscan2
- LINC01619 | n.1168G>C | RNA (SNP) | VAF 16/34 reads (47%) | called by muse, mutect2, varscan2
- LMO2 | c.-248G>A | 5'UTR (SNP) | VAF 30/64 reads (47%) | catalogued as rs755504726; called by muse, mutect2, varscan2
- LRP12 | c.1581-62G>A | Intron (SNP) | VAF 22/40 reads (55%) | called by muse, mutect2
- LSM8 | c.-7G>A | 5'UTR (SNP) | VAF 95/167 reads (57%) | called by muse, mutect2, varscan2
- MACF1 | c.15832-11345C>T | Intron (SNP) | VAF 52/107 reads (49%) | catalogued as COSV57127577; called by muse, mutect2, varscan2
- MACROD2 | c.*125_*129del | 3'UTR (DEL) | VAF 26/49 reads (53%) | catalogued as rs1003697148; called by mutect2, pindel, varscan2
- MAML2 | c.-352C>T | 5'UTR (SNP) | VAF 35/63 reads (56%) | called by muse, mutect2, varscan2
- MARCHF8 | c.*3548G>A | 3'UTR (SNP) | VAF 39/74 reads (53%) | called by muse, mutect2, varscan2
- MBD5 | c.*3036G>C | 3'UTR (SNP) | VAF 37/66 reads (56%) | called by muse, mutect2, varscan2
- MCC | c.*3716G>A | 3'UTR (SNP) | VAF 21/54 reads (39%) | called by muse, mutect2, varscan2
- MCM4 | c.-92G>A | 5'UTR (SNP) | VAF 17/25 reads (68%) | called by muse, mutect2, varscan2
- MED22 | c.*1318C>T | 3'UTR (SNP) | VAF 24/51 reads (47%) | called by muse, mutect2, varscan2
- MEGF11 | c.*1642G>A | 3'UTR (SNP) | VAF 23/46 reads (50%) | called by muse, mutect2, varscan2
- MEIS1 | c.240-372C>G | Intron (SNP) | VAF 59/112 reads (53%) | called by muse, mutect2, varscan2
- MOSPD3 | c.-38G>A | 5'UTR (SNP) | VAF 18/45 reads (40%) | catalogued as COSV99774947; called by muse, mutect2, varscan2
- MRPS25 | c.-82G>A | 5'UTR (SNP) | VAF 59/110 reads (54%) | called by muse, mutect2, varscan2
- MUC17 | c.-3C>G | 5'UTR (SNP) | VAF 54/111 reads (49%) | called by muse, mutect2, varscan2
- MUSK | c.*420G>A | 3'UTR (SNP) | VAF 29/45 reads (64%) | catalogued as rs969760681; called by muse, mutect2, varscan2
- NAP1L5 | c.*266C>G | 3'UTR (SNP) | VAF 24/41 reads (59%) | called by muse, mutect2, varscan2
- NEDD8 | c.*135G>A | 3'UTR (SNP) | VAF 29/53 reads (55%) | called by muse, mutect2, varscan2
- NFYC-AS1 | n.388C>T | RNA (SNP) | VAF 27/60 reads (45%) | catalogued as rs1385394028; called by muse, mutect2, varscan2
- NUBP2 | c.17-752G>C | Intron (SNP) | VAF 24/79 reads (30%) | called by muse, mutect2, varscan2
- NUCB2 | c.1256-110C>G | Intron (SNP) | VAF 16/28 reads (57%) | called by muse, mutect2, varscan2
- NXPH3 | c.-4G>A | 5'UTR (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2, varscan2
- OPTN | c.882+616G>A | Intron (SNP) | VAF 42/92 reads (46%) | called by muse, mutect2, varscan2
- OSBP | c.*74G>A | 3'UTR (SNP) | VAF 42/79 reads (53%) | called by muse, mutect2, varscan2
- PAPPA2 | c.*2570G>C | 3'UTR (SNP) | VAF 55/82 reads (67%) | called by muse, mutect2, varscan2
- PAQR3 | c.*126-158G>A | Intron (SNP) | VAF 16/46 reads (35%) | catalogued as rs1248039357; called by muse, mutect2, varscan2
- PAX4 | c.*307C>A | 3'UTR (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- PCDHGA9 | chr5:141402944 G>A | 5'Flank (SNP) | VAF 30/62 reads (48%) | called by muse, mutect2, varscan2
- PCYT1A | c.708+359A>G | Intron (SNP) | VAF 73/162 reads (45%) | called by muse, mutect2, varscan2
- PDCD10 | c.*435T>C | 3'UTR (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2, varscan2
- PDCD2 | c.658+98C>A | Intron (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- PDCL | c.*1090C>T | 3'UTR (SNP) | VAF 18/44 reads (41%) | called by muse, mutect2, varscan2
- PDPK1 | c.1344-2824G>A | Intron (SNP) | VAF 32/64 reads (50%) | called by muse, mutect2, varscan2
- PDZD9 | c.*112T>C | 3'UTR (SNP) | VAF 18/34 reads (53%) | called by muse, mutect2, varscan2
- PEF1 | c.*95C>G | 3'UTR (SNP) | VAF 26/55 reads (47%) | called by muse, mutect2, varscan2
- PEX16 | c.*586G>A | 3'UTR (SNP) | VAF 16/27 reads (59%) | called by muse, mutect2, varscan2
- PGM2L1 | c.*3819G>A | 3'UTR (SNP) | VAF 40/91 reads (44%) | called by muse, mutect2, varscan2
- PHF11 | c.-44C>A | 5'UTR (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- PIGQ | c.-9-1517C>G | Intron (SNP) | VAF 52/115 reads (45%) | called by muse, mutect2
- PLCL2 | c.327+47792G>A | Intron (SNP) | VAF 16/41 reads (39%) | called by muse, varscan2
- PLPP3 | c.-24G>A | 5'UTR (SNP) | VAF 39/82 reads (48%) | called by muse, mutect2, varscan2
- PON1 | c.*475C>G | 3'UTR (SNP) | VAF 27/71 reads (38%) | called by muse, mutect2, varscan2
- PPM1A | chr14:60245969 A>G | 5'Flank (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- PPP2R2A | c.83-5402C>T | Intron (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- PRKCH | c.*320G>A | 3'UTR (SNP) | VAF 20/37 reads (54%) | called by muse, mutect2, varscan2
- PRRG3 | c.*53T>A | 3'UTR (SNP) | VAF 24/24 reads (100%) | called by muse, mutect2, varscan2
- PTAR1 | c.*7883C>G | 3'UTR (SNP) | VAF 17/32 reads (53%) | called by muse, mutect2, varscan2
- PTPN7 | c.*982C>G | 3'UTR (SNP) | VAF 44/171 reads (26%) | called by muse, mutect2, varscan2
- QKI | c.*6718G>C | 3'UTR (SNP) | VAF 34/74 reads (46%) | called by muse, mutect2, varscan2
- RAD21 | chr8:116875429 C>A | 5'Flank (SNP) | VAF 26/60 reads (43%) | called by muse, mutect2, varscan2
- RBM15B | c.-82G>A | 5'UTR (SNP) | VAF 7/11 reads (64%) | called by muse, mutect2, varscan2
- RBM33 | chr7:155644533 G>A | 5'Flank (SNP) | VAF 16/32 reads (50%) | called by muse, mutect2, varscan2
- RFX4 | c.-174C>T | 5'UTR (SNP) | VAF 25/47 reads (53%) | called by muse, mutect2, varscan2
- RNF217 | c.*81G>C | 3'UTR (SNP) | VAF 54/115 reads (47%) | called by muse, mutect2, varscan2
- ROMO1 | chr20:35699398 C>T | 5'Flank (SNP) | VAF 30/69 reads (43%) | catalogued as rs1473389514; called by muse, mutect2, varscan2
- ROPN1 | c.116+704A>C | Intron (SNP) | VAF 9/211 reads (4%) | called by muse, mutect2
- RP9 | c.*375G>A | 3'UTR (SNP) | VAF 21/50 reads (42%) | called by muse, mutect2, varscan2
- RUFY2 | chr10:68407224 C>T | 5'Flank (SNP) | VAF 13/19 reads (68%) | called by muse, mutect2, varscan2
- SCIN | chr7:12570632 C>T | 5'Flank (SNP) | VAF 63/127 reads (50%) | catalogued as rs1336570420; called by muse, mutect2, varscan2
- SELL | c.-77C>T | 5'UTR (SNP) | VAF 134/173 reads (77%) | catalogued as COSV99357744; called by muse, mutect2, varscan2
- SEPTIN10 | c.30+456G>A | Intron (SNP) | VAF 48/99 reads (48%) | called by muse, mutect2, varscan2
- SFTA2 | c.61+11G>A | Intron (SNP) | VAF 30/53 reads (57%) | catalogued as rs1200827852; called by muse, mutect2, varscan2
- SGK1 | c.-152G>A | 5'UTR (SNP) | VAF 67/145 reads (46%) | called by muse, mutect2, varscan2
- SGTB | c.*953G>A | 3'UTR (SNP) | VAF 21/62 reads (34%) | catalogued as rs1338082677; called by muse, mutect2, varscan2
- SH3D19 | c.*642A>C | 3'UTR (SNP) | VAF 26/49 reads (53%) | called by muse, mutect2, varscan2
- SHPRH | c.*1626C>G | 3'UTR (SNP) | VAF 28/72 reads (39%) | called by muse, mutect2, varscan2
- SLC17A2 | chr6:25913115 C>A | 3'Flank (SNP) | VAF 41/86 reads (48%) | called by muse, mutect2, varscan2
- SLC25A45 | c.-18-63C>T | Intron (SNP) | VAF 50/84 reads (60%) | called by muse, mutect2, varscan2
- SLC27A2 | c.-133C>T | 5'UTR (SNP) | VAF 68/136 reads (50%) | called by muse, mutect2, varscan2
- SLC28A3 | c.*1829G>C | 3'UTR (SNP) | VAF 42/81 reads (52%) | called by muse, mutect2, varscan2
- SLC35B4 | c.*3328G>C | 3'UTR (SNP) | VAF 17/32 reads (53%) | called by muse, mutect2, varscan2
- SLC35E2B | chr1:1659531 G>A | 3'Flank (SNP) | VAF 44/96 reads (46%) | catalogued as rs542106951; called by muse, mutect2, varscan2
- SLITRK3 | c.*334G>A | 3'UTR (SNP) | VAF 7/114 reads (6%) | called by muse, mutect2
- SMARCA2 | c.3982-1878G>A | Intron (SNP) | VAF 69/149 reads (46%) | called by muse, mutect2, varscan2
- SMPD4BP | n.3559C>T | RNA (SNP) | VAF 22/60 reads (37%) | called by mutect2, varscan2
- SNURFL | n.183G>C | RNA (SNP) | VAF 60/62 reads (97%) | called by muse, mutect2, varscan2
- SNX18 | c.1774+202C>T | Intron (SNP) | VAF 16/37 reads (43%) | called by muse, mutect2, varscan2
- SOWAHC | c.*505G>A | 3'UTR (SNP) | VAF 16/31 reads (52%) | called by muse, mutect2, varscan2
- SOX6 | chr11:15972300 T>G | 3'Flank (SNP) | VAF 37/65 reads (57%) | called by muse, mutect2, varscan2
- SOX9 | c.*659A>C | 3'UTR (SNP) | VAF 21/41 reads (51%) | called by muse, mutect2, varscan2
- SPRTN | chr1:231338182 G>A | 5'Flank (SNP) | VAF 146/200 reads (73%) | catalogued as rs1307708176; called by muse, mutect2, varscan2
- SRSF5 | c.-108C>G | 5'UTR (SNP) | VAF 13/20 reads (65%) | catalogued as rs1385631050; called by muse, mutect2, varscan2
- ST3GAL3 | c.507-15C>T | Intron (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2, varscan2
- ST6GAL1 | c.805-46C>T | Intron (SNP) | VAF 19/42 reads (45%) | called by muse, mutect2, varscan2
- STAC | c.-278G>A | 5'UTR (SNP) | VAF 14/20 reads (70%) | called by muse, mutect2, varscan2
- STK11IP | c.619-63C>T | Intron (SNP) | VAF 15/38 reads (39%) | catalogued as rs1473215901; called by muse, mutect2, varscan2
- STRADA | c.*63G>A | 3'UTR (SNP) | VAF 16/31 reads (52%) | called by muse, mutect2, varscan2
- STRN3 | c.*1361G>A | 3'UTR (SNP) | VAF 50/111 reads (45%) | catalogued as rs1318129784; called by muse, mutect2, varscan2
- STX18 | chr4:4415862 C>T | 3'Flank (SNP) | VAF 35/67 reads (52%) | catalogued as rs142702229; called by muse, mutect2, varscan2
- SYTL2 | c.1459+1910G>T | Intron (SNP) | VAF 8/69 reads (12%) | called by muse, mutect2, varscan2
- TANGO6 | c.*17G>A | 3'UTR (SNP) | VAF 3/26 reads (12%) | catalogued as rs1392949186; called by muse, mutect2
- TBC1D12 | c.*223G>A | 3'UTR (SNP) | VAF 18/45 reads (40%) | called by muse, mutect2, varscan2
- TFIP11 | chr22:26491361 A>T | 3'Flank (SNP) | VAF 20/47 reads (43%) | called by muse, mutect2, varscan2
- TK1 | c.*351G>A | 3'UTR (SNP) | VAF 39/79 reads (49%) | called by muse, mutect2, varscan2
- TMEM131 | c.-6G>C | 5'UTR (SNP) | VAF 10/18 reads (56%) | called by muse, mutect2, varscan2
- TNKS | c.*1450C>T | 3'UTR (SNP) | VAF 33/69 reads (48%) | called by muse, mutect2, varscan2
- TNPO1 | c.-28G>A | 5'UTR (SNP) | VAF 23/43 reads (53%) | catalogued as rs1417025492, COSV61520486; called by muse, mutect2, varscan2
- TPPP | c.*3064C>T | 3'UTR (SNP) | VAF 78/155 reads (50%) | catalogued as rs1012632873, COSV62192527; called by muse, mutect2, varscan2
- TRIO | c.4614+43A>G | Intron (SNP) | VAF 18/34 reads (53%) | called by muse, mutect2, varscan2
- TRPM8 | c.942+328C>G | Intron (SNP) | VAF 18/45 reads (40%) | called by muse, mutect2, varscan2
- TSC22D2 | c.-685C>T | 5'UTR (SNP) | VAF 28/53 reads (53%) | called by muse, mutect2, varscan2
- TTC41P | n.142C>T | RNA (SNP) | VAF 68/151 reads (45%) | called by muse, mutect2, varscan2
- TTLL9 | c.70-7359G>A | Intron (SNP) | VAF 23/46 reads (50%) | catalogued as COSV100206640; called by muse, mutect2, varscan2
- TXNDC5 | c.*1074G>C | 3'UTR (SNP) | VAF 29/77 reads (38%) | called by muse, mutect2, varscan2
- UBA3 | c.1184+52G>C | Intron (SNP) | VAF 27/68 reads (40%) | called by muse, mutect2, varscan2
- UBXN2B | c.*196G>C | 3'UTR (SNP) | VAF 18/38 reads (47%) | called by muse, mutect2, varscan2
- UFD1 | chr22:19448276 G>C | 3'Flank (SNP) | VAF 19/39 reads (49%) | called by muse, mutect2, varscan2
- UPF2 | c.*287G>A | 3'UTR (SNP) | VAF 101/200 reads (51%) | called by muse, varscan2
- USF2 | c.110-9C>A | Intron (SNP) | VAF 17/27 reads (63%) | called by muse, mutect2, varscan2
- USP34 | c.-12G>A | 5'UTR (SNP) | VAF 53/110 reads (48%) | catalogued as rs781603364; called by mutect2, varscan2
- VCAN | c.*981G>A | 3'UTR (SNP) | VAF 30/56 reads (54%) | called by muse, mutect2, varscan2
- VCL | c.-61C>T | 5'UTR (SNP) | VAF 52/100 reads (52%) | catalogued as COSV99280318, COSV99280493, COSV99280941; called by muse, mutect2, varscan2
- VPS8 | c.1735-19C>G | Intron (SNP) | VAF 21/53 reads (40%) | called by muse, mutect2, varscan2
- WAPL | c.*686C>T | 3'UTR (SNP) | VAF 40/71 reads (56%) | called by muse, mutect2, varscan2
- WDR62 | c.2971+108G>A | Intron (SNP) | VAF 38/70 reads (54%) | catalogued as rs966825423; called by muse, mutect2, varscan2
- WDR75 | c.997+25G>A | Intron (SNP) | VAF 38/78 reads (49%) | catalogued as rs756619390; called by muse, mutect2, varscan2
- WNK3 | c.*2101C>T | 3'UTR (SNP) | VAF 19/20 reads (95%) | called by muse, mutect2, varscan2
- WSCD1 | c.*66C>A | 3'UTR (SNP) | VAF 10/21 reads (48%) | catalogued as rs879218173; called by muse, mutect2, varscan2
- XRCC5 | chr2:216109279 T>G | 5'Flank (SNP) | VAF 10/86 reads (12%) | called by muse, mutect2, varscan2
- XYLT1 | c.1289+58T>C | Intron (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- YPEL5 | c.*1000C>T | 3'UTR (SNP) | VAF 13/23 reads (57%) | called by muse, mutect2, varscan2
- YY1 | c.-63C>T | 5'UTR (SNP) | VAF 6/8 reads (75%) | called by muse, mutect2
- Y_RNA | chr7:75512345 A>C | 3'Flank (SNP) | VAF 13/28 reads (46%) | called by muse, mutect2, varscan2
- Z82198.2 | chr22:33166631 C>T | 3'Flank (SNP) | VAF 78/168 reads (46%) | called by muse, mutect2, varscan2
- ZBED4 | c.-227G>C | 5'UTR (SNP) | VAF 12/31 reads (39%) | catalogued as rs529500200; called by muse, mutect2, varscan2
- ZFAND2B | c.656+107T>G | Intron (SNP) | VAF 63/127 reads (50%) | called by muse, mutect2, varscan2
- ZFP30 | c.*1610C>G | 3'UTR (SNP) | VAF 4/11 reads (36%) | catalogued as COSV63623160; called by muse, mutect2
- ZNF204P | n.661G>A | RNA (SNP) | VAF 28/68 reads (41%) | called by muse, mutect2, varscan2
- ZNF563 | chr19:12333660 G>A | 5'Flank (SNP) | VAF 57/112 reads (51%) | catalogued as COSV53370769; called by muse, mutect2, varscan2
